Somatic mutation profile of tumor specimen C3N-00494-01 (aliquot CPT0012880006) from CPTAC case C3N-00494, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.0 years (24,122 days).
Specimen C3N-00494-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30848265-8aa9-4178-8a89-a80e36d5f62b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00494-31 (Blood Derived Normal), aliquot CPT0012980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38857795-d4d0-48d8-a3c5-929b5be23417

The open-access MAF lists 110 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Frame Shift Del 7, Nonsense Mutation 5, Intron 4, RNA 4, 3'UTR 3, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691439, COSV63973975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCDIN3D | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 53/325 reads (16%) | catalogued as COSV61702721; called by muse, mutect2, varscan2
- FAM13A | c.1390A>C p.S464R | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52008762; called by muse, mutect2, varscan2
- IL20RA | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1243457821; called by muse, mutect2, varscan2
- KCNA2 | c.317del p.L106* | Frame Shift Del (DEL) | VAF 142/393 reads (36%) | catalogued as COSV100316076; called by mutect2, pindel, varscan2
- KCTD8 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1243506439; called by muse, mutect2, varscan2
- LRRC1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63823304; called by muse, mutect2, varscan2
- MIA | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs577492559, COSV54572702; called by muse, mutect2, varscan2
- NECTIN1 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99871879; called by muse, varscan2
- OR14A2 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 91/137 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100825528; called by muse, mutect2, varscan2
- PITPNM3 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs941922159; called by muse, mutect2, varscan2
- PLCB1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV62046201; called by muse, mutect2, varscan2
- SIGIRR | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 80/289 reads (28%) | catalogued as rs778148546, COSV58985876; called by muse, mutect2, varscan2
- SLC19A3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CM131528; called by muse, mutect2, varscan2
- SLIT2 | c.4109G>T p.R1370L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV56587408; called by muse, mutect2
- SYTL3 | c.1266C>G p.D422E (on ENST00000611299 / NM_001242394.1; = p.D354E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV51914685; called by muse, mutect2, varscan2
- TAF3 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60203273; called by muse, mutect2, varscan2
- TMEM232 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV101459900; called by mutect2, varscan2
- TSNAXIP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs746465595; called by muse, mutect2, varscan2
- TTN | c.7720C>G p.P2574A (on ENST00000591111; = p.P2528A on NM_003319.4) | Missense Mutation (SNP) | VAF 31/240 reads (13%) | PolyPhen benign (0); catalogued as COSV59931673; called by muse, mutect2, varscan2
- VHL | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as CM023999, CS951541, COSV56543854, COSV56544010, COSV56545833; called by muse, mutect2, varscan2
- ZNF608 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs746685214; called by muse, mutect2
- ADAMTS2 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 187/516 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD10 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BCOR | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 165/234 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRF2 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 164/492 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- C2orf78 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- C3 | c.4815G>T p.W1605C | Missense Mutation (SNP) | VAF 253/743 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPE | c.3116T>G p.I1039S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGA1 | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- COL9A1 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 199/457 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL5 | c.554-9_567del p.X185_splice | Splice Site (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- DNAAF3 | c.1180A>G p.I394V (on ENST00000524407 / NM_001256715.2; = p.I441V on NM_178837.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAI2 | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELN | c.1556T>G p.I519S | Missense Mutation (SNP) | VAF 293/940 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EXOC2 | c.2725T>A p.L909M | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EXOC2 | c.2724C>A p.H908Q | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCN3 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FSIP2 | c.14408C>T p.S4803F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- GPR75 | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GREB1L | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRK7 | c.375_376del p.L126Qfs*14 | Frame Shift Del (DEL) | VAF 43/218 reads (20%) | called by mutect2, pindel, varscan2
- ITGAX | c.1390T>A p.S464T | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KATNB1 | c.1706G>C p.S569T | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KATNB1 | c.1708A>G p.K570E | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- KMT2C | c.247del p.T83Qfs*22 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- KRTAP11-1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- L3MBTL1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LYPLA2 | c.428del p.V143Gfs*3 | Frame Shift Del (DEL) | VAF 54/177 reads (31%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MEX3B | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MINDY1 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MKS1 | c.16T>A p.W6R | Missense Mutation (SNP) | VAF 146/509 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC19 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, varscan2
- MYLK | c.4494T>G p.Y1498* | Nonsense Mutation (SNP) | VAF 158/445 reads (36%) | called by muse, mutect2, varscan2
- NIPBL | c.7873A>T p.M2625L | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NRK | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUGGC | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBRM1 | c.1682del p.I561Tfs*8 | Frame Shift Del (DEL) | VAF 76/159 reads (48%) | called by mutect2, pindel, varscan2
- PTPN13 | c.6840del p.I2280Mfs*17 (on ENST00000411767 / NM_080683.3; = p.I2261Mfs*17 on NM_006264.3) | Frame Shift Del (DEL) | VAF 62/184 reads (34%) | called by mutect2, pindel, varscan2
- RAB36 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASD1 | c.479_482dup p.E161Dfs*224 | Frame Shift Ins (INS) | VAF 36/125 reads (29%) | called by mutect2, pindel, varscan2
- RMND5B | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SALL3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SNAP29 | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 186/591 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SORCS3 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPRED1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- STPG1 | c.532del p.R178Efs*23 (on ENST00000337248 / NM_001199013.2; = p.R131Efs*23 on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- SUDS3 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TBX22 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 75/229 reads (33%) | called by muse, mutect2, varscan2
- TCEAL4 | c.306T>A p.S102R | Missense Mutation (SNP) | VAF 116/165 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM26 | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.14998C>T p.Q5000* (on ENST00000591111; = p.Q4073* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | called by muse, mutect2, varscan2
- USP34 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZBED1 | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF707 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- A1CF | c.984C>G p.T328= | Silent (SNP) | VAF 138/361 reads (38%) | called by muse, mutect2, varscan2
- GFM1 | c.897C>T p.S299= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs763546447, COSV51833240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLUL | c.963C>T p.A321= | Silent (SNP) | VAF 289/509 reads (57%) | catalogued as rs770429686; called by muse, mutect2, varscan2
- GRID2IP | c.120C>G p.A40= | Silent (SNP) | VAF 87/500 reads (17%) | catalogued as rs937048848; called by muse, mutect2, varscan2
- HHLA1 | c.720C>G p.T240= | Silent (SNP) | VAF 89/233 reads (38%) | called by muse, mutect2, varscan2
- L3HYPDH | c.315C>T p.G105= | Silent (SNP) | VAF 69/215 reads (32%) | catalogued as rs1426392566; called by muse, mutect2
- LRRC70 | c.606T>C p.H202= | Silent (SNP) | VAF 72/216 reads (33%) | called by muse, mutect2, varscan2
- MAP6 | c.1185G>A p.R395= | Silent (SNP) | VAF 50/360 reads (14%) | called by muse, mutect2, varscan2
- MC2R | c.567C>T p.I189= | Silent (SNP) | VAF 83/186 reads (45%) | catalogued as rs267605119, COSV59617516; called by muse, mutect2, varscan2
- OSBPL3 | c.120A>G p.G40= | Silent (SNP) | VAF 79/255 reads (31%) | called by muse, mutect2, varscan2
- PWWP2B | c.747G>T p.R249= | Silent (SNP) | VAF 21/265 reads (8%) | called by muse, mutect2
- RGMA | c.375C>T p.R125= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV61235389; called by muse, mutect2, varscan2
- RPTOR | c.2226G>A p.L742= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- SMPD3 | c.1005A>T p.A335= | Silent (SNP) | VAF 79/210 reads (38%) | called by muse, mutect2, varscan2
- SNX2 | c.27G>A p.P9= | Silent (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- SORCS3 | c.876G>T p.R292= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV100865649, COSV63826086; called by muse, mutect2, varscan2
- SPTA1 | c.3102G>A p.L1034= | Silent (SNP) | VAF 69/510 reads (14%) | called by muse, mutect2, varscan2
- STK35 | c.27C>G p.A9= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- ZACN | c.825C>A p.L275= | Silent (SNP) | VAF 96/280 reads (34%) | called by muse, mutect2, varscan2
- AC011525.1 | n.866del | RNA (DEL) | VAF 27/158 reads (17%) | called by mutect2, pindel, varscan2
- AC093582.1 | n.174G>A | RNA (SNP) | VAF 31/346 reads (9%) | called by muse, mutect2
- ALX4 | c.*26C>G | 3'UTR (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- CROCC | c.1808+870C>A | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- FAM205BP | n.995T>C | RNA (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- GOLGA6L17P | n.110del | RNA (DEL) | VAF 30/287 reads (10%) | called by mutect2, pindel, varscan2
- MTHFD1 | c.2279+37A>C | Intron (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
- RBBP4 | c.1212+616A>T | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- SMTN | c.2603+1062G>A | Intron (SNP) | VAF 53/199 reads (27%) | catalogued as rs765152030; called by muse, mutect2, varscan2
- SOD1 | c.-33C>G | 5'UTR (SNP) | VAF 35/234 reads (15%) | catalogued as rs749428274, COSV54256572, COSV99531978; called by muse, mutect2, varscan2
- SYT5 | c.*40C>G | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*1522T>G | 3'UTR (SNP) | VAF 144/795 reads (18%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071635 T>G | 3'Flank (SNP) | VAF 106/394 reads (27%) | called by muse, varscan2
